Gene-level copy-number profile of tumor specimen C3L-07979-02 from CPTAC case C3L-07979, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 72.9 years (26,611 days).
Specimen C3L-07979-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c843fd86-a5ff-4297-8003-563124d7ef03.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-07979-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,729 have no estimate.
https://portal.gdc.cancer.gov/files/27f71e90-0698-4c92-96ad-6aa6216b418f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 522; copy number 1: 368; copy number 2: 3,971; copy number 3: 8,938; copy number 4: 23,220; copy number 5: 7,528; copy number 6: 7,908; copy number 7: 1,701; copy number 8: 2,200; copy number 9: 306; copy number 10: 1,687; copy number 11: 117; copy number 12: 181; copy number 13: 70; copy number 14: 35; copy number 15: 20; copy number 16: 1; copy number 19: 3; copy number 21: 21; copy number 22: 4; copy number 24: 31; copy number 25: 8; copy number 27: 37; copy number 40: 17.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:175,397,247–175,397,348, 1 gene (within-gene range 0–6): RNU6-1233P.
- chr3:175,609,479–175,776,333, 5 genes (within-gene range 0–6): RNU4-91P, AC119744.1, UBE2V1P2, RNU6-1317P, NAALADL2-AS1.
- chr4:90,838,903–91,112,790, 2 genes (within-gene range 0–1): TMSB4XP8, AC004054.1.
- chr4:181,064,089–181,265,145, 3 genes: LINC00290, AC019235.1, LINC02500.
- chr7:74,796,144–74,897,835, 4 genes: GTF2IRD2, STAG3L2, PMS2P5, Y_RNA.
- chr19:20,416,514–20,571,095, 3 genes (within-gene range 0–3): BNIP3P22, AC008554.1, BNIP3P23.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,411 genes in 43 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:156,298,624–156,615,288, 15 genes, copy number 9: VHLL, CCT3, TSACC, RHBG, AL139130.1, MIR9-1HG, MIR9-1, MEF2D, Y_RNA, AL365181.1, IQGAP3, TTC24, NAXE, GPATCH4, AL365181.4.
- chr1:207,150,205–207,309,292, 5 genes, copy number 10: AL445493.1, C4BPAP1, AL445493.2, C4BPAP2, AL596218.1.
- chr1:243,256,034–243,500,091, 1 gene, copy number 10 (within-gene range 5–10): SDCCAG8.
- chr1:243,346,176–244,709,033, 21 genes, copy number 10: MIR4677, AKT3, AL591721.1, FABP7P1, AL662889.1, AKT3-IT1, LINC02774, ZBTB18, AL590483.3, AL590483.1, AL590483.4, RN7SL148P, AL590483.2, C1orf100, AL645465.1, TGIF2P1, ADSS2, CATSPERE, CYCSP5, DESI2, AL451007.1.
- chr1:244,943,910–248,937,043, 147 genes, copy number 10 (broad region; genes not listed).
- chr2:85,133,392–85,905,199, 39 genes, copy number 11 (within-gene range 8–11): TCF7L1, TCF7L1-IT1, RNU6-674P, SNRPEP11, AC093162.1, TGOLN2, Y_RNA, PEBP1P2, RETSAT, ELMOD3, AC062037.1, Y_RNA, RN7SL113P, AC062037.2, CAPG, AC062037.3, SH2D6, Y_RNA, RN7SL251P, Y_RNA, RPSAP22, MAT2A, GGCX, VAMP8, RN7SL126P, VAMP5, RNF181, TMEM150A, USP39, C2orf68, SFTPB, GNLY, GPR160P1, RNU1-38P, ATOH8, MIR6071, AC105053.1, RN7SKP83, ST3GAL5.
- chr2:86,784,610–86,912,978, 4 genes, copy number 13 (within-gene range 8–13): CD8A, CD8B, ANAPC1P1, AC111200.1.
- chr2:89,297,264–91,659,972, 49 genes, copy number 11–13: IGKV1-37, IGKV2-38, IGKV1-39, IGKV2-40, 5S_rRNA, IGKV2D-40, IGKV1D-39, IGKV2D-38, IGKV1D-37, IGKV2D-36, IGKV1D-35, IGKV3D-34, IGKV1D-33, IGKV1D-32, IGKV3D-31, IGKV2D-30, IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21, IGKV3D-20, IGKV2D-19, IGKV2D-18, IGKV6D-41, IGKV1D-17, IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7, AC233266.1, AC233266.2, AC116050.1, LSP1P4.
- chr3:12,583,601–12,769,457, 3 genes, copy number 10 (within-gene range 5–10): RAF1, CRIP1P1, TMEM40.
- chr3:169,083,499–170,085,392, 27 genes, copy number 10: MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3.
- chr3:194,136,148–194,832,592, 28 genes, copy number 12: HES1, RN7SL215P, LINC02036, LINC02037, LINC02048, LINC00887, AC117469.1, CPN2, LRRC15, GP5, ATP13A3, AC108676.2, LINC00884, AC108676.1, RNU6-1101P, RPL23AP93, TMEM44-AS1, TMEM44, AC046143.1, AC046143.2, LSG1, FAM43A, AC106706.1, AC106706.2, LINC01968, AC090505.1, LINC01972, AC090505.2.
- chr4:49,486,926–49,524,185, 5 genes, copy number 11: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8.
- chr6:43,040,777–43,075,095, 2 genes, copy number 12 (within-gene range 8–12): KLC4, AL355385.2.
- chr6:43,074,331–45,377,953, 68 genes, copy number 10–12 (within-gene range 8–12) (broad region; genes not listed).
- chr6:118,757,518–118,935,162, 3 genes, copy number 10 (within-gene range 6–10): SELENOKP3, MCM9, ASF1A.
- chr7:6,365,441–15,068,651, 110 genes, copy number 9–21 (broad region; genes not listed).
- chr7:65,335,174–66,592,397, 41 genes, copy number 10 (within-gene range 8–10): RSL24D1P3, AC092685.1, ZNF92, AC114501.3, AC114501.1, AC114501.2, AC104057.1, AC073107.1, INTS4P2, CCT6P1, SNORA22, SNORA15B-2, AC073107.2, GTF2IP5, RNU6-912P, AC093582.1, RNU6-973P, VKORC1L1, GUSB, AC073261.1, AC068533.2, AC068533.1, ASL, AC068533.4, CRCP, AC068533.3, TPST1, RNU6-313P, LINC00174, GTF2IP9, SKP1P1, AC008267.2, AC008267.4, AC008267.7, AC008267.5, AC008267.6, GS1-124K5.4, AC008267.1, AC008267.3, AC006001.3, AC006001.4.
- chr7:67,278,714–67,362,950, 6 genes, copy number 9: SPDYE21, PMS2P4, Y_RNA, STAG3L4, AC006480.1, AC006480.2.
- chr8:96,645,242–100,663,415, 76 genes, copy number 10 (broad region; genes not listed).
- chr8:100,895,771–108,787,594, 128 genes, copy number 10 (broad region; genes not listed).
- chr8:122,485,194–122,781,071, 7 genes, copy number 12: LINC01151, AC108136.1, AC100872.1, AC100872.2, CDK5P1, AC016405.3, AC016405.2.
- chr8:122,977,026–125,541,373, 69 genes, copy number 12–14 (broad region; genes not listed).
- chr8:127,072,694–127,742,951, 10 genes, copy number 12–25: CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC.
- chr8:143,790,920–143,878,467, 9 genes, copy number 10: SCRIB, MIR937, PUF60, AC234917.3, AC234917.1, NRBP2, MIR6845, AC234917.2, EPPK1.
- chr10:120,984,966–120,985,596, 1 gene, copy number 9: AC010998.3.
- chr11:59,806,140–60,031,077, 8 genes, copy number 9 (within-gene range 4–9): MRPL16, CBLIF, TCN1, SRD5A3P1, OOSP1, AP000790.1, OOSP4A, OOSP4B.
- chr13:98,671,980–98,752,672, 2 genes, copy number 9: RN7SL60P, SLC15A1.
- chr13:102,760,023–103,066,417, 10 genes, copy number 13: AL157769.1, TEX30, POGLUT2, BIVM-ERCC5, BIVM, ERCC5, METTL21EP, AL137246.1, AL137246.2, SLC10A2.
- chr13:112,894,378–113,208,715, 13 genes, copy number 12 (within-gene range 8–12): MCF2L, AL356740.1, MCF2L-AS1, AL356740.2, AL356740.3, F7, F10, F10-AS1, KARS1P2, AL137002.2, PROZ, AL137002.1, PCID2.
- chr14:18,889,084–18,945,139, 5 genes, copy number 11: NEK2P1, NF1P7, MED15P1, AL929601.1, AL929601.2.
- chr16:46,469,341–46,790,407, 13 genes, copy number 9 (within-gene range 5–9): ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3.
- chr17:28,018,770–29,057,216, 91 genes, copy number 10–12 (broad region; genes not listed).
- chr17:74,770,529–74,949,992, 8 genes, copy number 10: NAT9, TMEM104, GRIN2C, FDXR, FADS6, USH1G, OTOP2, OTOP3.
- chr17:82,249,067–82,490,537, 20 genes, copy number 10 (within-gene range 6–10): AC132872.4, LINC01970, AC132872.1, CD7, SECTM1, TEX19, AC132938.4, UTS2R, AC132938.1, OGFOD3, AC132938.2, Y_RNA, HEXD, HEXD-IT1, CYBC1, AC132938.3, NARF, AC132938.5, NARF-AS1, NARF-IT1.
- chr19:27,638,483–30,957,192, 64 genes, copy number 14–40 (broad region; genes not listed).
- chr19:31,421,997–32,719,595, 25 genes, copy number 9–22: AC008992.1, AC008794.1, LINC02841, AC011525.1, AC011525.2, RNA5SP471, RNU6-967P, LINC01837, LINC01533, LINC01782, AC011518.1, RNA5SP472, ZNF507, AC007773.1, DPY19L3, PDCD5, ANKRD27, SNORA68B, RPS12P31, RN7SL789P, AC008474.1, RGS9BP, AC008736.1, NUDT19, AC008736.2.
- chr19:50,466,785–51,948,759, 121 genes, copy number 11–27 (broad region; genes not listed).
- chr20:16,177,933–64,327,972, 1,106 genes, copy number 9–14 (broad region; genes not listed).
- chr21:9,975,017–13,906,488, 45 genes, copy number 10–16: CR382285.1, CR382285.2, CR382287.1, CDRT15P8, AP003900.1, EIF3FP1, VN1R7P, AF254983.2, BAGE2, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1, AJ239318.1, FGF7P2, ANKRD30BP1, MIR3156-3, GTF2IP2, VN1R8P, LINC01674, SNX19P1, OR4K11P, OR4K12P, POTED, RNU6-286P, MIR3118-1, AL050303.2, GRAMD4P1, CXADRP1, AL050303.3, LONRF2P5, MIR8069-2, FEM1AP1, AL050303.1, TERF1P1, FAM207CP, GXYLT1P2, CNN2P7, ZNF114P1, CYP4F29P, SNX18P13.
- chr22:17,256,859–17,353,177, 3 genes, copy number 11: CECR3, CECR9, RN7SL843P.

Autosomal genes at a single copy (total copy number 1): 358. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
